Somatic mutation profile of tumor specimen MMRF_2186_1_BM_CD138pos (aliquot MMRF_2186_1_BM_CD138pos_T1_KHS5U_L08724) from MMRF case MMRF_2186, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.1 years (25,250 days).
Specimen MMRF_2186_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66cc7f27-ddd6-4821-accb-4c730c0fb0d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2186_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2186_1_PB_Whole_C3_KHS5U_L08723; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51133fc8-43da-4f4e-8dfe-48e4e3a4ef35

The open-access MAF lists 84 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 21, Intron 11, Silent 8, 5'UTR 4, Nonsense Mutation 2, Frame Shift Del 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 56/134 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 59/142 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC090517.4 | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1320789838; called by muse, mutect2, varscan2
- ACKR4 | c.332T>C p.M111T | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs1289652400; called by muse, mutect2, varscan2
- CRLF3 | c.839del p.G280Vfs*7 | Frame Shift Del (DEL) | VAF 149/388 reads (38%) | catalogued as COSV60837692; called by mutect2, pindel, varscan2
- CTNNA2 | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.872); catalogued as rs537442409, COSV100559937, COSV58167219, COSV99057391; called by muse, mutect2, varscan2
- DNAJC13 | c.5746G>A p.V1916I | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.554); catalogued as rs1316193917; called by muse, mutect2, varscan2
- DTX2 | c.1726G>A p.V576M | Missense Mutation (SNP) | VAF 140/277 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs748763928; called by muse, mutect2, varscan2
- GPT | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs145950433; called by muse, mutect2
- HRH2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 122/270 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51572847, COSV99199954; called by muse, mutect2, varscan2
- IGHJ1 | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 22/22 reads (100%) | catalogued as rs1555386767; called by muse, varscan2
- IGHV2-70 | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs554824536; called by muse, mutect2, varscan2
- IGLL5 | c.107A>T p.H36L | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs544159503, COSV73251092; called by muse, mutect2, varscan2
- MYH7B | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368227643; called by muse, mutect2, varscan2
- NR4A3 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs751483445; called by muse, mutect2, varscan2
- OR5AN1 | c.724T>C p.C242R | Missense Mutation (SNP) | VAF 130/250 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745562782; called by muse, mutect2, varscan2
- PPFIA4 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.397); catalogued as COSV99830286; called by muse, mutect2, varscan2
- RXFP3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs754698803, COSV57504049; called by muse, mutect2, varscan2
- TECTA | c.4501G>A p.A1501T | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1056976311, COSV50688097; called by muse, mutect2, varscan2
- UBE2N | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV58866995; called by muse, mutect2, varscan2
- ZFP42 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs1309230542, COSV58816656, COSV58817195; called by muse, mutect2, varscan2
- ASZ1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 83/157 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- C6orf89 | c.583A>G p.I195V (on ENST00000373685; = p.I202V on NM_152734.4) | Missense Mutation (SNP) | VAF 90/184 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CCND1 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- GLP1R | c.850T>A p.W284R | Missense Mutation (SNP) | VAF 85/169 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHJ6 | c.4_6delinsAA p.Y2Nfs*? | Frame Shift Del (DEL) | VAF 40/96 reads (42%) | called by pindel, varscan2*
- IQCD | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- KLHL13 | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 84/84 reads (100%) | called by muse, mutect2, varscan2
- NLGN1 | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 164/409 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUMA1 | c.4423A>C p.K1475Q | Missense Mutation (SNP) | VAF 155/344 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- OR8I2 | c.38T>A p.I13N | Missense Mutation (SNP) | VAF 192/420 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PCDHA8 | c.943T>G p.L315V | Missense Mutation (SNP) | VAF 92/217 reads (42%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PCLO | c.5531A>T p.Q1844L | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PKP4 | c.3480T>A p.Y1160* | Nonsense Mutation (SNP) | VAF 113/245 reads (46%) | called by muse, mutect2, varscan2
- SCYL2 | c.2674T>G p.S892A | Missense Mutation (SNP) | VAF 145/328 reads (44%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLIT2 | c.540-2A>C p.X180_splice | Splice Site (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2
- TMEM151B | c.911C>G p.A304G | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TRPS1 | c.3136A>G p.T1046A (on ENST00000220888 / NM_001330599.2; = p.T1059A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/273 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZDHHC24 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHMP2B | c.618A>G p.Q206= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as CM066003; called by muse, mutect2, varscan2
- GPR61 | c.429C>T p.Y143= | Silent (SNP) | VAF 113/208 reads (54%) | catalogued as rs376354304; called by muse, mutect2, varscan2
- MYOM2 | c.1590C>T p.S530= | Silent (SNP) | VAF 71/133 reads (53%) | called by muse, mutect2, varscan2
- PCDHB16 | c.936T>C p.V312= | Silent (SNP) | VAF 115/244 reads (47%) | called by muse, mutect2, varscan2
- RGS7 | c.1480C>T p.L494= (on ENST00000440928 / NM_001374810.1; = p.L423= on NM_001282773.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 132/297 reads (44%) | catalogued as COSV58535658; called by muse, varscan2
- TINAGL1 | c.918G>A p.A306= | Silent (SNP) | VAF 120/257 reads (47%) | catalogued as rs374434778; called by muse, mutect2, varscan2
- TNXB | c.8934G>A p.P2978= (on ENST00000647633; = p.P2731= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as rs745497457; called by muse, mutect2, varscan2
- TSC1 | c.1677C>T p.C559= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as rs368317116; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- AADAT | c.-209G>A | 5'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.*1256C>T | 3'UTR (SNP) | VAF 44/90 reads (49%) | catalogued as rs1027218940; called by muse, mutect2, varscan2
- ADRB1 | c.-209G>A | 5'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- AGMO | c.*106C>T | 3'UTR (SNP) | VAF 91/164 reads (55%) | called by muse, mutect2, varscan2
- ATE1 | c.*655T>C | 3'UTR (SNP) | VAF 75/191 reads (39%) | called by muse, mutect2, varscan2
- B4GALT7 | c.640-76C>G | Intron (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- C5orf51 | c.*4250C>T | 3'UTR (SNP) | VAF 38/98 reads (39%) | called by muse, mutect2, varscan2
- CALM3 | c.34+160G>C | Intron (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- CEBPA | c.*142T>A | 3'UTR (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- CELSR2 | c.*1517G>T | 3'UTR (SNP) | VAF 49/121 reads (40%) | called by muse, mutect2, varscan2
- DCBLD1 | c.*905A>G | 3'UTR (SNP) | VAF 30/51 reads (59%) | called by muse, mutect2, varscan2
- DNAJC21 | c.1494-84_1494-83del | Intron (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- GABRG1 | c.*4146T>G | 3'UTR (SNP) | VAF 53/126 reads (42%) | called by muse, mutect2, varscan2
- GCNT3 | c.*1247T>C | 3'UTR (SNP) | VAF 53/120 reads (44%) | called by muse, mutect2, varscan2
- H4-16 | c.*207G>C | 3'UTR (SNP) | VAF 46/93 reads (49%) | called by muse, mutect2, varscan2
- IGLON5 | c.*376G>T | 3'UTR (SNP) | VAF 7/129 reads (5%) | catalogued as rs1163848351; called by muse, mutect2
- KLF15 | c.*237C>T | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, varscan2
- KPNA5 | c.*45+87A>G | Intron (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- KRT77 | c.*763A>G | 3'UTR (SNP) | VAF 58/104 reads (56%) | catalogued as rs748596075; called by muse, mutect2, varscan2
- LAMC3 | c.*1765G>T | 3'UTR (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- LEPR | c.2674-2125T>C | Intron (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- LINC01551 | n.1255-5156C>A | Intron (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- MLEC | c.*2727G>A | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- NINJ1 | c.304+22G>A | Intron (SNP) | VAF 116/233 reads (50%) | called by muse, mutect2, varscan2
- PCYT2 | c.*107A>T | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- PDZD2 | c.*1286C>T | 3'UTR (SNP) | VAF 57/98 reads (58%) | called by muse, mutect2, varscan2
- PLIN5 | c.-7C>G | 5'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- PPARGC1B | c.*2436C>T | 3'UTR (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- PXDN | c.*102C>T | 3'UTR (SNP) | VAF 39/81 reads (48%) | catalogued as rs753920892; called by muse, mutect2, varscan2
- S1PR3 | c.-148+57G>C | Intron (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-2113T>C | 5'UTR (SNP) | VAF 55/56 reads (98%) | called by muse, mutect2, varscan2
- SON | c.6322-630A>G | Intron (SNP) | VAF 81/158 reads (51%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*5078A>G | 3'UTR (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2, varscan2
- TENM2 | c.503-120933G>A | Intron (SNP) | VAF 42/83 reads (51%) | catalogued as rs755054318, COSV101585692; called by muse, mutect2, varscan2
- TMSB4X | c.-17+147C>T | Intron (SNP) | VAF 100/102 reads (98%) | catalogued as COSV104432405; called by muse, mutect2, varscan2
- YWHAEP5 | n.156G>A | RNA (SNP) | VAF 45/312 reads (14%) | catalogued as rs1186154499; called by muse, mutect2, varscan2
- ZNF24 | c.*1590T>C | 3'UTR (SNP) | VAF 66/133 reads (50%) | called by muse, mutect2, varscan2
